Somatic mutation profile of tumor specimen TARGET-10-PAPHAM-09A (aliquot TARGET-10-PAPHAM-09A-01D) from TARGET case TARGET-10-PAPHAM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (1,003 days).
Specimen TARGET-10-PAPHAM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5111b885-a4b8-4e11-8b1e-d5a3c9cf1fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHAM-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHAM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9243088a-faef-49b9-850d-b0dd3f44e88e

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, 3'UTR 1, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC171 | c.1677C>G p.F559L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs147078175; called by muse, mutect2, varscan2
- CHMP7 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.366); catalogued as rs973607314; called by muse, mutect2
- CNTN4 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as rs377048968; called by muse, mutect2, varscan2
- ITGAE | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs189112267, COSV53989487; called by muse, mutect2, varscan2
- KCNG4 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as rs371214019; called by muse, mutect2, varscan2
- NYNRIN | c.3469C>A p.Q1157K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV66841490; called by muse, mutect2, varscan2
- ZNF514 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as rs1490055401; called by muse, mutect2
- FSIP2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); called by muse, mutect2
- RSBN1L | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEC63 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRGJP1 | c.1_2insGT p.T2Lfs*16 | Frame Shift Ins (INS) | VAF 33/51 reads (65%) | called by mutect2, pindel*, varscan2
- UNC80 | c.3970T>A p.F1324I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ADGRG4 | c.7125C>T p.H2375= | Silent (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- ADGRL3 | c.2910C>T p.F970= (on ENST00000506720 / NM_001322402.2; = p.F902= on NM_015236.6) | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2
- LUZP4 | c.219G>A p.R73= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- SEMG1 | c.63G>A p.V21= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- SULT1B1 | c.672C>T p.I224= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs368332134, COSV100150031; called by muse, mutect2, varscan2
- TANK | c.834G>T p.G278= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- TRIM60 | c.801C>T p.L267= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084328 C>T | 5'Flank (SNP) | VAF 8/80 reads (10%) | catalogued as rs1312866055; called by muse, mutect2
- KHDC1 | c.164-26C>T | Intron (SNP) | VAF 11/141 reads (8%) | catalogued as COSV64890658; called by muse, mutect2
- OR2T33 | c.*2C>G | 3'UTR (SNP) | VAF 19/98 reads (19%) | catalogued as COSV100531747; called by muse, mutect2, varscan2
